Somatic mutation profile of tumor specimen TCGA-TS-A7P0-01A (aliquot TCGA-TS-A7P0-01A-11D-A34C-32) from TCGA case TCGA-TS-A7P0, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 42.9 years (15,656 days).
Specimen TCGA-TS-A7P0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 478516d4-9101-4c23-b1b6-b355505c20f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A7P0-10A (Blood Derived Normal), aliquot TCGA-TS-A7P0-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ff6f0a5-b785-48c7-91d9-5c1a67eeb7a4

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 3, Splice Site 3, Intron 2, Nonsense Mutation 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC63 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as rs751735991; called by muse, mutect2, varscan2
- CSPG4 | c.6386G>A p.R2129K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1336541688; called by muse, mutect2, varscan2
- DLC1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs11990333; called by muse, mutect2, varscan2
- FANK1 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1379735515, COSV64156241; called by muse, mutect2, varscan2
- KCTD12 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 84/165 reads (51%) | catalogued as COSV58525046; called by muse, mutect2, varscan2
- LRRK2 | c.2790_2791del p.R931Tfs*10 | Frame Shift Del (DEL) | VAF 39/102 reads (38%) | catalogued as rs1362025551; called by mutect2, pindel, varscan2
- MGLL | c.529G>A p.G177R (on ENST00000398104 / NM_001003794.2; = p.G187R on NM_007283.6) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs866373886; called by muse, mutect2, varscan2
- NES | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV104427524; called by muse, mutect2, varscan2
- PCDH17 | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394633525, COSV64975003; called by muse, mutect2
- PCDHGB2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV54043492; called by muse, mutect2, varscan2
- PDLIM7 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs112356155; called by muse, varscan2
- PXDNL | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100681368, COSV62494974; called by muse, mutect2, varscan2
- TTN | c.46490C>T p.P15497L (on ENST00000591111; = p.P8073L on NM_003319.4) | Missense Mutation (SNP) | VAF 32/197 reads (16%) | PolyPhen probably damaging (0.999); catalogued as COSV100628721; called by muse, mutect2, varscan2
- XIRP1 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs1270533660; called by muse, mutect2, varscan2
- CSMD3 | c.3132T>A p.H1044Q (on ENST00000297405 / NM_001363185.1; = p.H940Q on NM_052900.3) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2
- FANK1 | c.234G>T p.R78S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FARP1 | c.2615G>A p.S872N | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.696); called by mutect2, varscan2
- FRAS1 | c.1198C>G p.P400A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJA3 | c.1056del p.S353Afs*46 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- GRIN1 | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HUNK | c.1861T>G p.S621A | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- IKBKE | c.48del p.Q17Rfs*21 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- LGI3 | c.764G>C p.S255T | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- LHFPL4 | c.227C>G p.T76S | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NRAP | c.1653G>A p.W551* (on ENST00000359988 / NM_001322945.2; = p.W516* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- PTH2R | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAD21 | c.1241A>G p.D414G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2
- RPS10-NUDT3 | c.697+2T>C p.X233_splice | Splice Site (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- SELE | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- SELP | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SGF29 | c.527T>A p.I176N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- SIGLEC10 | c.503G>C p.W168S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SPATA31D1 | c.4205C>A p.A1402D | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM138 | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- TUSC3 | c.1029-1G>T p.X343_splice | Splice Site (SNP) | VAF 49/112 reads (44%) | called by muse, mutect2, varscan2
- UNC50 | c.644-1G>A p.X215_splice | Splice Site (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- UNC5B | c.2746G>T p.D916Y | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- VAV3 | c.1295G>A p.C432Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H7A | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF689 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACP7 | c.480C>T p.G160= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1319694508; called by muse, mutect2
- ADCY8 | c.1677C>A p.L559= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV53909175; called by muse, mutect2, varscan2
- GLDC | c.723A>T p.G241= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2
- INVS | c.2713A>C p.R905= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99317333; called by muse, mutect2, varscan2
- PCDH17 | c.2019G>C p.L673= | Silent (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- SOGA1 | c.2610C>T p.L870= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs1478585823; called by muse, mutect2
- SRPK2 | c.1806C>A p.I602= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs777538690; called by muse, mutect2, varscan2
- TEKT4 | c.1110G>A p.E370= | Silent (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- USH2A | c.801C>T p.V267= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs547847873; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825756 T>C | 5'Flank (SNP) | VAF 4/25 reads (16%) | catalogued as rs1050334569; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152447095 C>A | 3'Flank (SNP) | VAF 72/211 reads (34%) | called by mutect2, varscan2
- P3H1 | c.2055+156G>A | Intron (SNP) | VAF 46/157 reads (29%) | catalogued as rs776996199; called by muse, mutect2, varscan2
- SV2C | c.581-20971G>A | Intron (SNP) | VAF 66/192 reads (34%) | called by muse, mutect2, varscan2
